Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84J, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84J-01A (Primary Tumor).

[page 1 of 3]
SEX

DOCTOR :
DOC. ADDRESS :

D.O.B.

ADDRESS :

COLL. DATE
DATE RECEIVED

ACC. NO. :

LAB. NO. :

WARD
CONSULTANT :

HISTOPATHOLOGY REPORT

COPY TO:

SUPPLEMENTARY AND FINAL REPORT

SPECIMEN:

- A. Occipital tumour biopsy.
- B. Occipital tumour.

Representative formalin fixed paraffin embedded tissue sections were submitted for FISH [fluorescence in situ hybridization] studies to assess 1p, 19q and EGFR. The FISH studies were performed in the following manner:

The results of the studies (which have been reported separately) demonstrated no loss of 1p and no loss of 19q, and EGFR amplification was not detected.

Review of the morphology and immunohistochemical findings has been undertaken in light of these FISH results. The original diagnosis remains essentially unchanged; - despite the absence of 1p 19q codeletions, the findings are still favoured to represent WHO III anaplastic oligodendroglioma. Nonetheless, it remains difficult to completely exclude a high-grade mixed oligoastrocytoma (WHO Grade IV highly anaplastic oligoastrocytoma) in which high-grade oligodendroglioma is the predominant morphological pattern.

PATHOLOGIST:

DATED:

ELECTRONICALLY VALIDATED:

----- END OF REPORT FOR -----

*ICD-3
Oligodendroglioma, grade III
C44.2
Site Brain, supratentorial NOS
path C71.0
Brain, occipital lobe C71.4
9/10/30/13*

[page 2 of 3]
Patient Results

Anatomic Pathology results Performed from

Corrected Results

SEA

DOC. ADDRESS

D.O.B.

ADDRESS :

COLL. DATE

DATE RECEIVED

ACC. NO. :

WARD

LAB. NO. :

CONSULTANT :

HISTOPATHOLOGY REPORT

COPY TO:

SPECIMEN:

- A. Occipital tumour biopsy.
- B. Occipital tumour.

CLINICAL:

Brain tumour. Looks like metastasis - no known primary.

MACROSCOPIC:

- A. Haemorrhagic brain tissue 10 x 7 x 2mm.

INTRA-OPERATIVE ASSESSMENT - FROZEN SECTION/IMPRINT CYTOLOGY

High grade glioma.

BLOCK KEY:

1:tissue remaining from frozen section, 2:remaining tissue

- B. Multiple fragments of tan/brown tissue, measuring in aggregate approximately 40 x 30 x 7mm.

MICROSCOPIC:

A. and B. All tissue submitted has been processed and examined. Examination of permanent sections confirms the intraoperative diagnosis of high grade glioma. The parenchyma is extensively effaced by a malignant glioma containing small areas of necrosis. The neoplastic cells possess variably pleomorphic and hyperchromatic nuclei with coarse chromatin and small nucleoli and perinuclear cytoplasmic clearing. In many areas these cells lie in a background that contains frequent interconnecting small thin walled blood vessels as well as occasional calcium deposits. Occasional multinucleate tumour giant cells are present. Throughout the tumour there are frequent mitotic figures and apoptotic bodies. There is widespread endothelial proliferation. There is quite extensive immunohistochemical positivity for GFAP, whilst scattered cells stain positively for p53. The GFAP positivity highlights some mini-gemistocytes. The proliferation index, as measured by MIB-1 (Ki67), is variable, and approximates to 10-15%. The differential diagnosis rests obvious high grade glioma rests between an anaplastic oligodendroglioma (WHO Grade III) and a high grade mixed oligoastrocytoma, which, on the basis of the presence of necrosis, would be WHO Grade IV [highly anaplastic oligoastrocytoma]. FISH studies are pending, but on the basis of the findings to date, anaplastic oligodendroglioma (WHO Grade III) is favored.

CONCLUSION:

A. and B. Occipital tumour: High grade glioma, which on the basis of the findings to date, is favored to represent anaplastic oligodendroglioma (WHO Grade III).

Comment: The differential diagnosis includes a high grade mixed oligoastrocytoma, which, on the basis of the presence of necrosis, would be WHO

Request

End of Report

Printed from

Page 2 of 3

[page 3 of 3]
Patient Results
Anatomical Pathology results - Performed from

Histopathology

Corrected Results

Grade IV [highly anaplastic oligoastrocytoma], but anaplastic oligodendroglioma is favored. Representative formalin fixed paraffin embedded tissue sections have been submitted for FISH [fluorescence in situ hybridization] studies to assess 1p, 19q and EGFR, and a final conclusion and report will be issued when these are complete.

REGISTRAR: -
PATHOLOGIST.

DATED:
ELECTRONICALLY VALIDATED:

----- END OF REPORT FOR -----

Criteria

	Yes	No

Source: NCI Genomic Data Commons file 126fffab-8e00-4bd2-99fb-1633b2c407dc (TCGA-TM-A84J.D3563493-4083-479F-A172-8E856AD793C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).